Somatic mutation profile of tumor specimen TCGA-ET-A2N3-01B (aliquot TCGA-ET-A2N3-01B-21D-A23M-08) from TCGA case TCGA-ET-A2N3, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 34.5 years (12,603 days).
Specimen TCGA-ET-A2N3-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a86823a-1e26-4f31-af95-28346db2e3f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A2N3-10A (Blood Derived Normal), aliquot TCGA-ET-A2N3-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01d65926-d525-42c5-8a6c-adee2d696218

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2, Frame Shift Ins 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ESYT2 | c.2697A>T p.E899D (on ENST00000613624; = p.E823D on NM_020728.3) | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99276820; called by muse, mutect2, varscan2
- GRM6 | c.727dup p.V243Gfs*40 | Frame Shift Ins (INS) | VAF 63/186 reads (34%) | catalogued as rs281865186; ClinVar: not provided; called by mutect2, varscan2
- OLFM1 | c.269G>A p.R90H (on ENST00000371793 / NM_001282611.2; = p.R72H on NM_006334.4) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs868665665, COSV52962294; called by muse, mutect2, varscan2
- PLEKHA3 | c.451-1G>C p.X151_splice | Splice Site (SNP) | VAF 41/80 reads (51%) | catalogued as COSV99317748; called by muse, mutect2, varscan2
- SLC31A2 | c.207G>C p.E69D | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV99406928; called by muse, mutect2, varscan2
- GCAT | c.696dup p.C233Mfs*16 | Frame Shift Ins (INS) | VAF 20/34 reads (59%) | called by mutect2, varscan2
- ADPRH | c.522G>A p.A174= | Silent (SNP) | VAF 29/270 reads (11%) | catalogued as rs762437182, COSV100813276; called by muse, mutect2, varscan2
- DCAF4L2 | c.18G>A p.P6= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as rs1444148435, COSV100150950; called by muse, mutect2, varscan2
